CPTAC case GTEX-R55F-0011-R10A-SM-HAKXY — Brain (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9e72332c-6932-4890-a0fd-4fc18716fd83

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Dead; Days to death: 0 days.

Exposures
- Alcohol history: No.

Biospecimens (1 sample)
- Sample PT-R55F-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2.
